Somatic mutation profile of tumor specimen MP2PRT-PANUVV-TMP1-A (aliquot MP2PRT-PANUVV-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PANUVV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.8 years (1,015 days).
Specimen MP2PRT-PANUVV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba47241b-0bc2-4006-832f-5088ad0fb4ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANUVV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANUVV-NB1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/afe2624b-2a68-4b29-9d76-3068bc30771b

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 48/133 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs1057519725, COSV55498939; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 26/372 reads (7%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- CADM1 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 17/270 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753952579; called by muse, mutect2
- GRIK2 | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 73/326 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.935); catalogued as rs188883833; called by muse, mutect2, varscan2
- MRPL45 | c.13A>G p.I5V | Missense Mutation (SNP) | VAF 84/549 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1179413434; called by muse, varscan2
- ULK4 | c.3200C>T p.S1067L | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs752576516, COSV57201414; called by muse, mutect2, varscan2
- HTR2C | c.855C>T p.N285= | Silent (SNP) | VAF 210/517 reads (41%) | catalogued as rs782359396, COSV52211534; called by muse, mutect2, varscan2
